CPTAC case C3N-03802 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/e3ef9d58-6464-4bb0-bd7d-32e4e1eb31b8

Demographics
Sex at birth: male; Race: asian; Year of birth: 1952; Vital status: Alive; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 65.7 years (24,015 days); Year of diagnosis: 2018; Last known disease status: With tumor; Days to last known disease status: 364 days; Progression or recurrence: yes; Days to recurrence: 158 days; Days to last follow up: 364 days.
   Pathology details: Greatest tumor dimension: 3.7 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 364 days; Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 158 days; Karnofsky performance status: 50; ECOG performance status: 3.
- Days to follow up: 364 days; Disease response: With Tumor; Karnofsky performance status: 50; ECOG performance status: 3.

Other clinical attributes
- Weight: 95 kg; Height: 172 cm; BMI: 32.11.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 5; Cigarettes per day: 20; Tobacco smoking onset year: 2012; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker; Exposure duration years: 10.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03802-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 170 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03802-21: Section location: Temporal Lobe; Percent tumor nuclei: 75; Percent necrosis: 10.
- Sample C3N-03802-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
